HCMI case HCM-CSHL-0586-C32 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Larynx. Index date (day 0 for every day count below): first patient visit.
https://portal.gdc.cancer.gov/cases/a1d1b84f-51e1-49cc-b13d-905292264b92

Demographics
Sex at birth: male; Days to birth: -23,360 days (64.0 years before the index date); Year of birth: 1954; Vital status: Dead; Days to death: 75 days.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C32.0; Tissue or organ of origin: Larynx, NOS; Site of resection or biopsy: Glottis; Laterality: Left; Classification of tumor: primary; AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; Tumor grade: G3; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Pathology details: Transglottic extension: Present.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 14 days.
   Treatment given: Treatment type: Radiation, Intensity-Modulated Radiotherapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 28 days; Days to treatment end: 64 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 75.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 66 kg; Height: 178 cm; BMI: 20.8.

Exposures
- Alcohol type: Beer.
- Tobacco smoking status: Current Smoker; Pack years smoked: 50; Alcohol intensity: Drinker; Alcohol drinks per day: 6; Alcohol days per week: 7.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (3 samples)
- Sample HCM-CSHL-0586-C32-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample HCM-CSHL-0586-C32-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-CSHL-0586-C32-85D: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
